Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A6S3, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A6S3-01A (Primary Tumor).

[page 1 of 3]
CCCF ICD-O-3
Oligodendroglioma, grade II 9450/3
path
Oligodendroglioma NOS 9450/3
Site Brain, supratentorial
C71.2
Q 7/24/13

Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: (Age:) Location: Received:
Gender: M Accnt: Reported:
Physician(s):
Phy Location:

Clinical History

man experiences dizziness and lightheadedness for about nine months. On imaging, there is a focal expansion of the cerebral cortex with extension into the white matter in the right frontal lobe. The lesion has few punctate areas of enhancement.

Operative Diagnoses

Brain lesion

Operation / Specimen

A: Brain tumor, biopsy

Pathologic Diagnosis

A, B. Brain, site not specified, excision: Oligodendroglioma (WHO 2).

1p,19q LOH (codeletion): Positive.

MIB-1: 3.5%

Se Microscopy Description and Comment.

Comment

The sections contain portions of a glial neoplastic proliferation that has an oligodendroglial phenotype. The neoplasm diffusely infiltrates the brain. There are very sparse mitotic figures, and the MIB-1 proliferation index is low at about 3.5% in the more active areas. There is not microvascular cellular proliferation or tumor necrosis. The tumor has LOH (codeletion) of 1p, 19q. The features are those of a low histological grade oligodendroglioma (WH) 2). The results of MGMT testing will be reported in an addendum.
Electronically Signed Out

Consultant:

Senior Staff Pathologist
Senior Staff Pathologist

Procedures/Addenda

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: Date Reported:

Surgical Pathology

Page 2 of 3

Interpretation

POSITIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is detected.

Informative loci are: D1S1592, D1S552, D19S412, PLA2G4C

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (A2). DNA extracted from a corresponding blood specimen was used as a normal reference control.
H and E slide was examined and tumor DNA was enriched by microdissection
TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3

[page 2 of 3]
markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

Senior Staff Pathologist

MGMT Promoter Methylation

Date Ordered: **Date Reported:**

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (A2)

H and E slide was examined and tumor DNA was enriched by microdissection

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the

detection of methylated MGMT promoter sequences.

Surgical Pathology

Page 3 of 3

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

[page 3 of 3]
provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

Senior Staff Pathologist

Intra-Operative Consultation

A.

Brain tumor, biopsy: Diffusely infiltrating glioma (C/W oligodendroglioma? Mixed oligoastrocytoma?).
Touch preparation smears performed at and results reported to the Physician of
Record.

Senior

Staff Pathologist

Gross Description

A.

Brain tumor, biopsy:

CONTAINER LABEL: brain tumor

FIXATIVE: formalin

GENERAL: 3.1 x 2.5 x 0.5 cm aggregate of tan pink soft tissue and possible clotted blood.

SECTIONS: 3, NS L, 1730

Microscopic Description

IMMUNOHISTOCHEMISTRY: The neoplastic cells are strongly and uniformly IDH1-R132 positive. With the MIB-1

there is a proliferation index of 3.5% in the more active areas.

ICD-9(s): 237.5 237.5

Billing Fee Code(s):

Unilateral/Synchronous Primary Noted		

Source: NCI Genomic Data Commons file 34ff6163-8de4-4f45-bbd0-ce16ffeca9eb (TCGA-DU-A6S3.913A3754-B550-431A-B9B7-2825D1B51015.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).